Somatic mutation profile of tumor specimen C3N-00959-02 (aliquot CPT0079830009) from CPTAC case C3N-00959, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.7 years (24,361 days).
Specimen C3N-00959-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08ca1321-080d-4185-a0c4-c2110b3035f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00959-31 (Blood Derived Normal), aliquot CPT0080770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84eab86f-7220-49bd-bdda-2129f4e4a090

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 48/287 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.1555_1558del p.N519Efs*3 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs753633581; called by mutect2, pindel, varscan2
- AP3B1 | c.2614G>A p.V872M | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as rs765162490; called by muse, varscan2
- BNC2 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1290133928, COSV66147486; called by muse, mutect2
- CCBE1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 60/395 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs368065685; called by muse, mutect2, varscan2
- COL22A1 | c.4025G>A p.G1342E | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280111, COSV57325689; called by muse, mutect2, varscan2
- OLFM1 | c.814C>T p.R272C (on ENST00000371793 / NM_001282611.2; = p.R254C on NM_014279.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747137531, COSV53276091; called by muse, mutect2, varscan2
- RHBDF2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs149960669; called by muse, mutect2, varscan2
- RYR1 | c.10531G>A p.V3511M | Missense Mutation (SNP) | VAF 98/512 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376389988; called by muse, mutect2, varscan2
- SETD2 | c.4994A>G p.D1665G | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57441240; called by muse, mutect2
- TTLL8 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747118338, COSV56723098; called by muse, mutect2
- ANKRD34B | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDAN1 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KANSL3 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LRP3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MROH2A | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2
- OLR1 | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PADI4 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDZD2 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- PIN4 | c.193-8_193delinsTTTTTTATT p.X65_splice (on ENST00000664196; = p.X40_splice on NM_006223.4) | Splice Site (ONP) | VAF 6/52 reads (12%) | called by mutect2*, pindel
- SETD2 | c.795dup p.H266Tfs*8 | Frame Shift Ins (INS) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- SMARCC1 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TTN | c.11987dup p.N3996Kfs*11 (on ENST00000591111; = p.N3950Kfs*11 on NM_003319.4) | Frame Shift Ins (INS) | VAF 15/151 reads (10%) | called by mutect2, pindel, varscan2
- ZNF800 | c.127_129del p.I43del | In Frame Del (DEL) | VAF 24/126 reads (19%) | called by pindel, varscan2
- ALOX12B | c.603C>T p.R201= | Silent (SNP) | VAF 65/326 reads (20%) | catalogued as COSV100047402; called by muse, mutect2, varscan2
- APOA5 | c.429C>T p.R143= | Silent (SNP) | VAF 49/345 reads (14%) | catalogued as rs754727126; called by muse, mutect2, varscan2
- CLHC1 | c.1716T>C p.S572= | Silent (SNP) | VAF 52/167 reads (31%) | called by muse, mutect2, varscan2
- DNM3 | c.609T>G p.V203= | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- ERBB2 | c.1566T>G p.G522= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- FLRT1 | c.1044C>T p.A348= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs140908634; called by muse, mutect2, varscan2
- GADL1 | c.474G>A p.A158= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs187843448; called by muse, mutect2
- LTBP2 | c.1920C>A p.T640= | Silent (SNP) | VAF 90/542 reads (17%) | called by muse, mutect2, varscan2
- SLC2A5 | c.684G>A p.A228= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- UNC5CL | c.1092C>T p.I364= | Silent (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- LYPD6B | c.-35C>G | 5'UTR (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
